Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-7920, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-7920-01A (Primary Tumor).

[page 1 of 2]
Final Diagnosis

Proximal small bowel, distal stomach, head of pancreas, and distal common bile duct, pancreaticoduodenectomy (Whipple resection):

Pancreatic ductal adenocarcinoma.

- Histologic grade: Moderately differentiated
- Tumor size: 3.2 cm maximum gross tumor dimension.
- Tumor site: Pancreatic head.
- Surgical margins:
- Proximal (gastric) margin: Negative.
- Distal (small bowel) margin: Negative.
- Distal pancreatic resection margin: Negative.
- Pancreatic retroperitoneal (uncinate) margin: Negative.
- Common bile duct margin: Negative.
- Closest surgical margin: Tumor less than 1 mm from inked uncinate margin.
- Lymph-vascular invasion: Not identified.
- Perineural invasion: Present.
- Regional lymph nodes: 12 identified regional lymph nodes negative for metastatic neoplasm (0/12).
- AJCC pathologic stage: **pT2,N0** (per the [redacted] edition of AJCC Staging System)

Separately submitted bile duct margin (with FSA):
Negative for neoplasm.

Separately submitted portal vein margin (with FSB):
Negative for neoplasm.

Gallbladder:
Cholelithiasis.
Chronic cholecystitis.

Clinical Information

Obstructive jaundice.

Frozen Section Diagnosis

A. Gross: 1 elongated yellow-tan fragment approximately 1.5 x 0.4 cm. Entirely submitted for FS.
FSA Bile duct margin: benign with area of hyperplasia. Suggest that additional section be submitted from margin if possible.
[redacted]

B. Portal vein margin - yellow-tan elongated fragment measuring approximately 1 x 0.4 cm. All frozen.

[page 2 of 2]
C. Long suture = pancreatic margin (FS) - black
Short suture = unicate margin
Single suture = retroperitoneal margin

FSB Portal vein margin: vein and adjacent benign ductules. [REDACTED]

FSC-1 Pancreatic margin (long suture - black): negative for carcinoma. [REDACTED]

FSC-2 Tumor for FS

Pancreatic ductal adenocarcinoma [REDACTED]

Gross Description

"FSA." All frozen section tissue is submitted in cassette "FSA."

"FSB." All frozen section tissue is submitted in cassette "FSB."

"FSC1." All frozen section tissue is submitted in cassette "FSC1."

"FSC2." All frozen section tissue is submitted in cassette "FSC2."

"C, NFSC." The specimen consists of a portion of stomach (1.5 x 4.7 x 0.9 cm), duodenum (37.1 x 7.5 cm) and pancreatic head (7.0 x 4.6 x 4.5 cm). The specimen has been oriented as follows: long suture = pancreatic margin, short suture = unicate margin and single suture = retroperitoneal margin. The pancreatic margin has previously been inked black by the pathologist. The remaining margins are inked as follows: unicate margin orange and retroperitoneal margin green. A portion of the pancreatic margin has been submitted at frozen section. The remaining margins will be shaved and submitted. The common bile duct margin is inked blue, shaved and submitted. Previous sectioning reveals a 2.0 x 1.4 x 2.2 cm pale tan, firm, ill-defined area. The radial margin has previously been inked black by the pathologist. This area grossly appears to obstruct the pancreatic duct margin and comes to within 1.6 cm of the pancreatic margin, less than a millimeter of the unicate, less than a millimeter of the radial margin, and 0.2 cm of the retroperitoneal margin. The remaining pancreatic parenchyma is yellow-tan and lobulated. On examination of the stomach, normal rugal folds are present. No masses or areas of interest are identified. On examination of the duodenum, the serosa is gray-brown with mild adhesions. Upon opening, the mucosa is pale tan to tan-brown and unremarkable. The ampulla of Vater is probe-patent. No masses or areas of interest are identified.

The attached peripancreatic and periduodenal fat are examined for lymph nodes. On examination, 10 possible lymph nodes are identified. These range in size from 0.2 to 1.9 cm. "C1," gastric and duodenal margins; "C2," remaining pancreatic margin; "C3," common bile duct margin and sections immediately after pancreatic margin; "C4-C6," firm area to include radial margin; "C7-C8," firm area to include unicate and retroperitoneal margins; "C9," ampulla of Vater; "C10," gastric mucosa; "C11," duodenal mucosa; "C12-C13," peripancreatic lymph nodes; "C14," periduodenal lymph nodes, representative.

"D, Gallbladder." The specimen consists of a 6.9 x 2.3 x 2.2 cm unopened gallbladder. The serosa is blue-gray to red-gray, and the wall averages 0.2 cm in thickness. Within the lumen is thin, green-brown bile and less than 50 yellow-gray, ovoid and fragmented stones measuring up to 1.1 cm. There is also a small amount of clotted blood. The cystic duct is obstructed. The mucosa is bile stained and denuded with moderate trabeculation. The surgical margin is inked black. "D," 3p, representative.

[REDACTED] Received in formalin is one yellow cassette labeled as follows: [REDACTED] This will be submitted for routine processing. [REDACTED]

Performing Lab

Source: NCI Genomic Data Commons file ae8a7e98-95b6-48e2-b2ec-8b2d48e4a7f0 (TCGA-HZ-7920.55B6499B-F3C0-487B-ACBA-354B6C4F29F8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).